Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012426-09A.2 (aliquot TARGET-15-SJMPAL012426-09A.2-01D) from TARGET case TARGET-15-SJMPAL012426, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.4 years (511 days).
Specimen TARGET-15-SJMPAL012426-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95b59e0f-cb49-4811-b599-562e4da8253d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012426-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012426-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4187226b-054a-4569-85df-2efa3dcb9812

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLCL1 | c.2330T>C p.I777T | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1454732776; called by muse, mutect2, varscan2
- LTB4R2 | c.752C>A p.A251E (on ENST00000528054; = p.A220E on NM_019839.5) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.03); called by muse, mutect2
- ST6GALNAC6 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 7/85 reads (8%) | PolyPhen probably damaging (0.982); called by muse, mutect2
- AKR1C1 | c.666C>T p.H222= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs377035250; called by muse, mutect2, varscan2
- C11orf52 | c.240C>T p.D80= | Silent (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- CD4 | c.1173C>G p.S391= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV50593549; called by muse, mutect2
- SLC6A14 | c.606C>T p.N202= | Silent (SNP) | VAF 48/50 reads (96%) | catalogued as rs781876726, COSV64148728; called by mutect2, varscan2
- IRF8 | c.358+53C>A | Intron (SNP) | VAF 6/79 reads (8%) | catalogued as rs1370864661; called by muse, mutect2
